Somatic mutation profile of tumor specimen TCGA-HW-8321-01A (aliquot TCGA-HW-8321-01A-11D-2395-08) from TCGA case TCGA-HW-8321, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 31.4 years (11,474 days).
Specimen TCGA-HW-8321-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69941be2-8a42-4ec5-9b19-c9426d1359ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HW-8321-10A (Blood Derived Normal), aliquot TCGA-HW-8321-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3b33dc8-632a-47ce-bf84-a9f06c0bc62a

The open-access MAF lists 36 somatic variants for this specimen: 27 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 8, Nonsense Mutation 2, Frame Shift Ins 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 31/101 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 49/67 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AP2M1 | c.623G>C p.G208A | Missense Mutation (SNP) | VAF 37/248 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53047077; called by muse, mutect2, varscan2
- CABP4 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs770541032, COSV56885070; called by muse, mutect2, varscan2
- CDHR4 | c.495+6C>T | Splice Region (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100323718; called by muse, mutect2, varscan2
- CMTM7 | c.304G>A p.V102M | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs765824035, COSV58549868; called by muse, mutect2
- DAG1 | c.1079A>G p.D360G | Missense Mutation (SNP) | VAF 37/241 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV58182632; called by muse, mutect2, varscan2
- DBF4B | c.1477C>G p.P493A | Missense Mutation (SNP) | VAF 55/172 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV59259002; called by muse, mutect2, varscan2
- DNMT3A | c.2678G>A p.W893* | Nonsense Mutation (SNP) | VAF 22/75 reads (29%) | catalogued as rs750515748, COSV53039322, COSV53041651, COSV53048797; called by muse, mutect2, varscan2
- FGFR4 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52800971; called by muse, mutect2, varscan2
- FMNL3 | c.1811A>T p.D604V | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV53298128; called by muse, mutect2, varscan2
- FZD5 | c.1444C>A p.L482I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.14); catalogued as COSV54942873; called by muse, mutect2, varscan2
- HELZ2 | c.3403G>A p.V1135M (on ENST00000467148 / NM_001037335.2; = p.V566M on NM_033405.3) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.405); catalogued as rs979994962, COSV64409039; called by muse, mutect2
- KIAA1841 | c.730G>C p.V244L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.731); catalogued as rs1448523091, COSV54372686; called by mutect2, varscan2
- MYO3A | c.355G>A p.G119S | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs928785273, COSV56320307; called by muse, mutect2, varscan2
- OR2A1 | c.233C>A p.P78H | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101283411; called by muse, mutect2
- POGLUT1 | c.600G>A p.W200* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | catalogued as COSV55155396; called by muse, mutect2, varscan2
- SOAT2 | c.1444T>A p.F482I | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as COSV56858697; called by muse, mutect2, varscan2
- ST6GAL2 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 13/181 reads (7%) | PolyPhen probably damaging (0.991); catalogued as rs144935783; called by muse, mutect2
- TRHDE | c.2276G>A p.R759Q | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as rs745307313, COSV53830756, COSV53833514; called by muse, mutect2, varscan2
- TRIM15 | c.410T>C p.L137P | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV64988977; called by muse, mutect2, varscan2
- USP43 | c.2939A>T p.D980V | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV53299823; called by muse, mutect2, varscan2
- WDR81 | c.5488G>A p.D1830N (on ENST00000409644 / NM_001163809.2; = p.D779N on NM_152348.4) | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1419559741, COSV100489128; called by muse, mutect2
- ZNF334 | c.749C>T p.S250F | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV61617988; called by muse, mutect2, varscan2
- ZNF804A | c.1432C>G p.P478A | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV100168032, COSV56436063; called by muse, mutect2, varscan2
- ZNF804B | c.2282A>C p.N761T | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as COSV60816730; called by muse, mutect2, varscan2
- ASPM | c.1614dup p.E539Rfs*16 | Frame Shift Ins (INS) | VAF 18/139 reads (13%) | called by mutect2, pindel, varscan2
- AMER1 | c.210T>C p.P70= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV57655126; called by muse, mutect2, varscan2
- DPPA3 | c.108G>A p.T36= | Silent (SNP) | VAF 61/169 reads (36%) | catalogued as rs766520317, COSV61502743; called by muse, mutect2, varscan2
- GPR63 | c.1203G>A p.K401= | Silent (SNP) | VAF 36/104 reads (35%) | catalogued as COSV57739614; called by muse, mutect2, varscan2
- IL1RL2 | c.843A>G p.R281= | Silent (SNP) | VAF 47/144 reads (33%) | catalogued as COSV51813055; called by muse, mutect2, varscan2
- THSD4 | c.597C>T p.S199= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as COSV55961641; called by muse, mutect2
- TMEM40 | c.417A>C p.P139= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV53145106; called by muse, mutect2, varscan2
- TNXB | c.9873C>T p.A3291= (on ENST00000647633; = p.A3044= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/108 reads (36%) | catalogued as rs544342649, COSV64473730; ClinVar: likely benign; called by muse, mutect2, varscan2
- USP12 | c.207G>A p.A69= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as rs142426104; called by muse, mutect2, varscan2
- NUDCD3 | c.509+16777T>C | Intron (SNP) | VAF 22/214 reads (10%) | called by muse, mutect2, varscan2
